Somatic mutation profile of cancer-model specimen HCM-BROD-0444-C43-85O (Mixed Adherent Suspension, passage 9; aliquot HCM-BROD-0444-C43-85O-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0444-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.4 years (22,064 days).
Specimen HCM-BROD-0444-C43-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea006a44-36ae-4562-a261-70c9da296c8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0444-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0444-C43-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb1d6ff7-752c-4c98-800e-cff22e242903

The open-access MAF lists 905 somatic variants for this specimen: 535 protein-altering or splice-affecting, 297 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 478, Silent 297, Intron 34, Nonsense Mutation 34, 5'Flank 12, 3'UTR 10, Splice Region 10, 5'UTR 8, RNA 7, Splice Site 5, Frame Shift Del 3, Frame Shift Ins 3.

Variants (750 of 905; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1914_1916dup p.T639dup (on ENST00000288602 / NM_001374244.1; = p.T599dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 328/485 reads (68%) | catalogued as rs727502902; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NEXMIF | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 232/487 reads (48%) | catalogued as rs878854425, COSV50022161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.5645G>A p.R1882Q | Missense Mutation (SNP) | VAF 193/396 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs794727444, CM136053, CM145316, COSV51836760, COSV51839118; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3203G>A p.G1068E | Missense Mutation (SNP) | VAF 191/499 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.345); catalogued as rs1342193834, COSV55289748; called by muse, mutect2
- ABCC9 | c.2417G>A p.G806E | Missense Mutation (SNP) | VAF 156/339 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771669791; called by muse, mutect2, varscan2
- ABI3BP | c.2087G>A p.G696E | Missense Mutation (SNP) | VAF 193/391 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as COSV52552812; called by muse, mutect2, varscan2
- ACTN3 | c.637-1G>A p.X213_splice | Splice Site (SNP) | VAF 171/346 reads (49%) | catalogued as COSV72207668; called by muse, mutect2, varscan2
- ADAMTS16 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 196/387 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.425); catalogued as rs1418819406; called by muse, mutect2, varscan2
- ADGRF1 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 205/960 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs762544665; called by muse, mutect2, varscan2
- ADH1A | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 450/525 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV52924354; called by muse, mutect2, varscan2
- AFF2 | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 228/510 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV53996155, COSV54007286; called by muse, mutect2, varscan2
- AGTR2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 278/537 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs1163188247, COSV64156615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGXT2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 227/452 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561216704; called by muse, mutect2, varscan2
- AHNAK | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 256/537 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs114553252; called by muse, mutect2, varscan2
- AHSG | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 221/382 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99890047; called by muse, mutect2, varscan2
- ANK3 | c.4708C>T p.P1570S | Missense Mutation (SNP) | VAF 208/436 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1003753635; called by muse, mutect2, varscan2
- ANKFN1 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100593315; called by muse, mutect2, varscan2
- APOB | c.11915G>A p.G3972E | Missense Mutation (SNP) | VAF 146/297 reads (49%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV51946074; called by muse, mutect2, varscan2
- ARHGAP21 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 194/383 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1265976883; called by muse, mutect2, varscan2
- ARMC4 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.159); catalogued as COSV53468692; called by muse, mutect2, varscan2
- ASTN2 | c.1957C>T p.R653C (on ENST00000313400 / NM_001365069.1; = p.R602C on NM_014010.5) | Missense Mutation (SNP) | VAF 198/459 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759200691, COSV57763735, COSV57810099; called by muse, mutect2, varscan2
- ASTN2 | c.1493C>T p.S498F (on ENST00000313400 / NM_001365069.1; = p.S447F on NM_014010.5) | Missense Mutation (SNP) | VAF 202/383 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV57782772; called by muse, mutect2, varscan2
- ATP1B4 | c.823G>A p.D275N (on ENST00000218008 / NM_001142447.3; = p.D271N on NM_012069.5) | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV54314240; called by muse, mutect2, varscan2
- BAP1 | c.66C>T p.F22= | Splice Region (SNP) | VAF 551/551 reads (100%) | catalogued as rs1559593101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP2 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV66577868; called by muse, mutect2, varscan2
- BMP4 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 138/326 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753312749, COSV55415763; called by muse, mutect2, varscan2
- BRINP2 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 218/429 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762582867, COSV64180145; called by muse, mutect2, varscan2
- BRINP3 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 182/396 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs200210126; called by muse, mutect2, varscan2
- BSDC1 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 177/382 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs138922587; called by muse, mutect2, varscan2
- C3orf62 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs770343603, COSV57985227; called by muse, mutect2, varscan2
- C6 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 195/394 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs746657514; called by muse, mutect2, varscan2
- C7 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 209/435 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV57472567; called by muse, mutect2, varscan2
- CACNA1E | c.6922G>A p.E2308K (on ENST00000367573 / NM_001205293.3; = p.E2265K on NM_000721.4) | Missense Mutation (SNP) | VAF 152/275 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs769144197; called by muse, mutect2, varscan2
- CAMSAP3 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 332/683 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV99351901; called by muse, mutect2, varscan2
- CCDC185 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 257/489 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs1055826533; called by muse, mutect2, varscan2
- CD163L1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 222/468 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58014686; called by muse, mutect2, varscan2
- CDH6 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 120/285 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs777622672, COSV54064764; called by muse, mutect2, varscan2
- CEACAM21 | c.823G>A p.E275K (on ENST00000401445 / NM_001098506.4; = p.E274K on NM_033543.6) | Missense Mutation (SNP) | VAF 242/512 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV51813263; called by muse, mutect2, varscan2
- CEP152 | c.2020T>G p.C674G | Missense Mutation (SNP) | VAF 159/285 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858382; called by muse, mutect2, varscan2
- CEP57 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 184/387 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1422459007; called by muse, mutect2, varscan2
- CFAP69 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 70/451 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1168482952; called by muse, mutect2, varscan2
- CGNL1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 175/365 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV55569994; called by muse, mutect2, varscan2
- CHTF18 | c.668T>C p.L223S | Missense Mutation (SNP) | VAF 287/574 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs774782274; called by muse, mutect2, varscan2
- CLEC19A | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 220/470 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV71854365; called by muse, mutect2, varscan2
- CNR2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 170/395 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.441); catalogued as rs567833720, COSV65692174; called by muse, mutect2, varscan2
- CNTNAP4 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 214/423 reads (51%) | catalogued as COSV56698027, COSV56705357; called by muse, mutect2, varscan2
- COBLL1 | c.1211C>T p.S404F (on ENST00000392717; = p.S366F on NM_014900.5) | Missense Mutation (SNP) | VAF 231/451 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766568141; called by muse, mutect2, varscan2
- COL14A1 | c.3886C>T p.P1296S | Missense Mutation (SNP) | VAF 344/715 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV52849671, COSV52857235; called by muse, mutect2, varscan2
- CSPG4 | c.5677C>T p.R1893C | Missense Mutation (SNP) | VAF 286/556 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs897200627; called by muse, mutect2, varscan2
- CUX2 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs866861740, COSV55632203; called by muse, mutect2, varscan2
- CYP19A1 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 133/274 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs142652579; called by muse, mutect2, varscan2
- CYP7B1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 200/921 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV59587400; called by muse, mutect2, varscan2
- DCC | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 194/427 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59110035; called by muse, mutect2, varscan2
- DCX | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 348/716 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as CD010102; called by muse, mutect2, varscan2
- DDX55 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 149/296 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs1229217236; called by muse, mutect2, varscan2
- DEFB116 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 221/402 reads (55%) | catalogued as COSV68721937, COSV68722127; called by muse, mutect2, varscan2
- DNAAF5 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 374/530 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs373188379, COSV52417205; called by muse, mutect2
- DNAH10 | c.12895G>A p.E4299K (on ENST00000409039; = p.E4238K on NM_207437.3) | Missense Mutation (SNP) | VAF 296/613 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53022652; called by muse, mutect2, varscan2
- DNAH17 | c.1809G>A p.M603I | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as COSV101102152; called by muse, mutect2, varscan2
- DNAH5 | c.12631G>A p.E4211K | Missense Mutation (SNP) | VAF 222/492 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762673561, COSV54204698, COSV54216995; ClinVar: uncertain significance; called by muse, mutect2
- DNAH5 | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 242/544 reads (44%) | catalogued as COSV54239235, COSV54246940; called by muse, mutect2
- DNAH6 | c.6742C>T p.Q2248* | Nonsense Mutation (SNP) | VAF 130/256 reads (51%) | catalogued as rs867541838, COSV99404233; called by muse, mutect2, varscan2
- DNAH7 | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 221/429 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as rs1260735627; called by muse, mutect2, varscan2
- DNER | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59162499; called by muse, mutect2, varscan2
- DPPA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 112/206 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs1476085353, COSV61502941; called by muse, mutect2, varscan2
- DSCAM | c.5455G>A p.E1819K | Missense Mutation (SNP) | VAF 249/518 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68030907; called by muse, mutect2, varscan2
- EDEM2 | c.705C>T p.V235= | Splice Region (SNP) | VAF 143/318 reads (45%) | catalogued as rs146048652; called by muse, mutect2, varscan2
- ENOX1 | c.1745C>G p.P582R | Missense Mutation (SNP) | VAF 155/313 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54899567; called by muse, mutect2, varscan2
- ENPEP | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 225/256 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765435416; called by muse, mutect2, varscan2
- EPHB2 | c.1843G>A p.E615K (on ENST00000400191 / NM_001309193.2; = p.E616K on NM_004442.7) | Missense Mutation (SNP) | VAF 221/430 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV65863907; called by muse, mutect2, varscan2
- ERV3-1 | c.1802C>T p.T601I | Missense Mutation (SNP) | VAF 325/443 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs978437290; called by muse, mutect2, varscan2
- ESX1 | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 139/633 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.915); catalogued as rs200088361, COSV65423956; called by muse, mutect2, varscan2
- EXOC4 | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 429/593 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54115912; called by muse, mutect2, varscan2
- FAM47A | c.1555T>C p.S519P | Missense Mutation (SNP) | VAF 108/481 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867589029, COSV60496026; called by muse, varscan2
- FAM71D | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV61295136; called by muse, mutect2, varscan2
- FAT4 | c.12629C>T p.S4210L | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58702376; called by muse, mutect2
- FGFR2 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 138/299 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs763622845, COSV60647057, COSV60653143; called by muse, mutect2, varscan2
- FILIP1L | c.2374G>A p.D792N (on ENST00000354552 / NM_182909.3; = p.D552N on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 213/494 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766486139; called by muse, mutect2, varscan2
- FLI1 | c.385+8G>A | Splice Region (SNP) | VAF 114/114 reads (100%) | catalogued as rs202161078; called by muse, mutect2, varscan2
- FN3K | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 133/271 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs768119555, COSV100333382; called by muse, mutect2, varscan2
- FOLR1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 195/413 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100398573, COSV56617235; called by muse, mutect2, varscan2
- FRMPD4 | c.42-4C>T | Splice Region (SNP) | VAF 152/301 reads (50%) | catalogued as rs866518317; called by mutect2, varscan2
- GABRA3 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.086); catalogued as rs868315790, COSV100942422; called by muse, mutect2, varscan2
- GABRA6 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 128/308 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV50881948; called by muse, mutect2, varscan2
- GAPT | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 166/352 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs374776433; called by muse, mutect2, varscan2
- GAS6 | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 213/773 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.275); catalogued as rs770035055, COSV100581339; called by muse, mutect2, varscan2
- GJA10 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 220/424 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV101005331; called by muse, mutect2, varscan2
- GORAB | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 112/242 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs760812590, COSV63025986; called by muse, mutect2
- GPR39 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 173/370 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.034); catalogued as rs778803979; called by muse, mutect2, varscan2
- GRIN2A | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 226/492 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV58021494; called by muse, mutect2, varscan2
- GRK1 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 341/538 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766547270; called by muse, mutect2, varscan2
- GSDMD | c.1139-5C>T | Splice Region (SNP) | VAF 209/856 reads (24%) | catalogued as rs1273103106; called by muse, mutect2, varscan2
- GZMB | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 153/316 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as rs763072582, COSV53540596; called by muse, mutect2, varscan2
- HERC5 | c.1966A>G p.K656E | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs747098849; called by muse, mutect2, varscan2
- HHIP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 303/349 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369873424; called by muse, mutect2, varscan2
- HLA-DRB1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 254/1958 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1335525050, COSV63514519; called by muse, mutect2
- HTR2C | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 284/586 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV52220085; called by muse, varscan2
- IGHA1 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 145/803 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs774279646; called by muse, mutect2, varscan2
- IGHA2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 162/578 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1555452761; called by muse, varscan2
- IL27RA | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 195/391 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.092); catalogued as COSV54600233; called by muse, mutect2, varscan2
- IL37 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 176/328 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs867056062, COSV54492147; called by muse, mutect2, varscan2
- INA | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 158/337 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs757776233, COSV63976619; called by muse, mutect2, varscan2
- INHBC | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 251/466 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs149645850; called by muse, mutect2, varscan2
- INPPL1 | c.3322A>G p.T1108A | Missense Mutation (SNP) | VAF 302/661 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53355646; called by muse, mutect2, varscan2
- JAKMIP2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 124/245 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54596724; called by muse, mutect2, varscan2
- KCNB2 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 220/839 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV73049213; called by muse, mutect2, varscan2
- KDM1B | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 171/600 reads (29%) | catalogued as rs1430835643; called by muse, mutect2, varscan2
- KHDRBS2 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 218/440 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55430938; called by muse, mutect2, varscan2
- KIF4B | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 225/467 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV70528946, COSV70531999; called by muse, mutect2, varscan2
- KLHL38 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 197/863 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs752428942, COSV58089275; called by muse, mutect2, varscan2
- KNDC1 | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 265/491 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV58839212; called by muse, mutect2, varscan2
- LCT | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 204/444 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV51555802; called by muse, mutect2, varscan2
- LGALS16 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 105/200 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs764476165; called by muse, mutect2, varscan2
- LIN7A | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 204/477 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866830191, COSV54020298; called by muse, mutect2, varscan2
- LIPE | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 357/696 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs752615475; called by muse, mutect2, varscan2
- LMBRD2 | c.1718A>G p.N573S | Missense Mutation (SNP) | VAF 137/257 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1358449572; called by muse, mutect2, varscan2
- LMO7 | c.2197C>T p.R733C (on ENST00000357063; = p.R414C on NM_005358.5) | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749357751, COSV58532445; called by muse, mutect2, varscan2
- LPCAT2 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 210/398 reads (53%) | catalogued as rs768233963; called by muse, mutect2, varscan2
- LRFN2 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 194/928 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs1326906123; called by muse, mutect2, varscan2
- LUZP4 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 94/189 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV64218730; called by muse, mutect2, varscan2
- LYN | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 232/599 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1327427054, COSV70205649; called by muse, mutect2, varscan2
- MAGEB18 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 259/530 reads (49%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.936); catalogued as COSV57463376, COSV57465510; called by muse, mutect2, varscan2
- MAGEC2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 275/542 reads (51%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.811); catalogued as rs1362108453; called by muse, mutect2, varscan2
- MAGEC3 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 294/615 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as rs867666403, COSV100025696, COSV68924062; called by muse, mutect2, varscan2
- MAP2K2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 175/400 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.426); catalogued as COSV53565396; called by muse, mutect2, varscan2
- MAVS | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63927084; called by muse, mutect2, varscan2
- MCHR2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 183/388 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs142259467, COSV56001077; called by muse, mutect2, varscan2
- MGAM | c.4814C>T p.S1605F | Missense Mutation (SNP) | VAF 733/1018 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101527335, COSV72073448; called by muse, mutect2, varscan2
- MLXIPL | c.2372T>G p.V791G | Missense Mutation (SNP) | VAF 237/999 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100515152; called by muse, mutect2, varscan2
- MNDA | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 198/413 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1480747048; called by muse, mutect2, varscan2
- MORC1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 125/256 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1453242500, COSV51716702; called by muse, mutect2, varscan2
- MROH2B | c.4307C>T p.S1436L | Missense Mutation (SNP) | VAF 145/348 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs867528082, COSV68182690; called by muse, mutect2, varscan2
- MTMR1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 195/360 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782029024; called by muse, mutect2, varscan2
- MUC12 | c.970C>T p.P324S (on ENST00000379442; = p.P181S on NM_001164462.1) | Missense Mutation (SNP) | VAF 937/1301 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1377708481; called by muse, mutect2, varscan2
- MUC12 | c.1463C>T p.P488L (on ENST00000379442; = p.P345L on NM_001164462.1) | Missense Mutation (SNP) | VAF 784/1048 reads (75%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.556); catalogued as rs1431281550; called by muse, varscan2
- MUC17 | c.6554C>T p.P2185L | Missense Mutation (SNP) | VAF 829/1134 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs770277203; called by muse, mutect2, varscan2
- MYH1 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 224/424 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56845725; called by muse, mutect2, varscan2
- MYH1 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 217/488 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV56846051, COSV56857179; called by muse, mutect2, varscan2
- MYH1 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 127/262 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV56847119; called by muse, mutect2, varscan2
- MYH2 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 195/360 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV55441089; called by muse, mutect2, varscan2
- MYO15A | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 254/550 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs771141820, COSV99234310; called by muse, mutect2, varscan2
- MYO3A | c.3903G>A p.M1301I | Missense Mutation (SNP) | VAF 138/284 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99780590; called by muse, mutect2
- MYOCD | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 261/541 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV58506546; called by muse, mutect2, varscan2
- MYOM1 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 258/524 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99866100; called by muse, mutect2, varscan2
- NAA16 | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 180/352 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101038451; called by muse, mutect2, varscan2
- NALCN | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 403/594 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745318137, COSV99217547; called by muse, mutect2, varscan2
- NDST4 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as rs1190760162, COSV52107697; called by muse, mutect2, varscan2
- NDST4 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 40/543 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV52115889; called by muse, mutect2
- NFKBIE | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 307/1160 reads (26%) | PolyPhen benign (0.421); catalogued as COSV51488912; called by muse, mutect2, varscan2
- NLRP4 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 231/437 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100015586, COSV56709094; called by muse, mutect2, varscan2
- NOL6 | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 159/317 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as rs190107267; called by muse, mutect2, varscan2
- NPAP1 | c.1419G>T p.L473F | Missense Mutation (SNP) | VAF 183/430 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV61509891; called by muse, mutect2, varscan2
- NPHS2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 179/353 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.685); catalogued as rs896307266, CM021649, COSV62635074; called by muse, mutect2, varscan2
- NPY4R | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 88/410 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781805373; called by muse, mutect2
- NRG1 | c.1340C>T p.S447L (on ENST00000405005 / NM_013964.5; = p.S452L on NM_013956.5) | Missense Mutation (SNP) | VAF 232/515 reads (45%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as rs774023178, COSV55151534; called by muse, mutect2, varscan2
- NRXN2 | c.3958G>A p.V1320M | Missense Mutation (SNP) | VAF 273/603 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs780052134; called by muse, mutect2, varscan2
- NSG2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 181/328 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV100292681, COSV57459529; called by muse, mutect2, varscan2
- NUGGC | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 193/451 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58432839; called by muse, mutect2, varscan2
- NXF3 | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 170/364 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV67702838; called by muse, mutect2, varscan2
- NXF3 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 176/388 reads (45%) | catalogued as rs755460265, COSV67703268; called by muse, mutect2, varscan2
- OCIAD1 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 260/412 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767850383, COSV51900510; called by muse, mutect2, varscan2
- OR4C46 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as COSV60218496; called by muse, mutect2, varscan2
- OR4E2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 208/455 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201192739, COSV57731367; called by muse, mutect2, varscan2
- OR4K14 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 147/310 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs1420560514; called by muse, mutect2, varscan2
- OR4L1 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 177/423 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370818199, COSV59849562; called by muse, mutect2, varscan2
- OR4N2 | c.507T>A p.C169* | Nonsense Mutation (SNP) | VAF 266/1040 reads (26%) | catalogued as COSV60055179; called by muse, varscan2
- OR5AP2 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 204/389 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs778885273; called by muse, mutect2, varscan2
- OR5B3 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 153/351 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.042); catalogued as COSV100511855; called by muse, mutect2, varscan2
- OR5W2 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 188/396 reads (47%) | catalogued as COSV100747611; called by muse, mutect2, varscan2
- OR6C75 | c.597T>A p.F199L | Missense Mutation (SNP) | VAF 160/307 reads (52%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); catalogued as COSV58551669; called by muse, varscan2
- OR6N2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59412883; called by muse, mutect2, varscan2
- OR6P1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 146/344 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58110179; called by muse, mutect2
- OR8D4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 202/203 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100361960, COSV58431603; called by muse, mutect2, varscan2
- OR8D4 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 203/204 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV100361964; called by muse, mutect2, varscan2
- OTUD6A | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 329/682 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57973372; called by muse, mutect2, varscan2
- PCARE | c.3440C>T p.S1147L | Missense Mutation (SNP) | VAF 277/596 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs368208413; called by muse, mutect2, varscan2
- PCDHB10 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 180/400 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as rs782669371; called by muse, mutect2, varscan2
- PCDHB10 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 215/446 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs267600435, COSV53376257; called by muse, mutect2, varscan2
- PCDHGA4 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 146/316 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54056472; called by muse, mutect2
- PCDHGA8 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 149/326 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1285768639; called by muse, mutect2, varscan2
- PCDHGC5 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 224/424 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV52760355; called by muse, mutect2, varscan2
- PIBF1 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58325615; called by muse, mutect2, varscan2
- PIWIL2 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 177/361 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs374676378, COSV63249666; called by muse, mutect2, varscan2
- PKP3 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 291/291 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1487377468; called by muse, mutect2, varscan2
- PLXNA1 | c.5680C>A p.L1894M | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as COSV99302590; called by muse, mutect2, varscan2
- PNCK | c.649G>A p.D217N (on ENST00000340888 / NM_001366975.1; = p.D300N on NM_001039582.3) | Missense Mutation (SNP) | VAF 204/459 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1461755892; called by muse, mutect2, varscan2
- PNPLA1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 461/653 reads (71%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100463236; called by muse, mutect2, varscan2
- PRR27 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 337/380 reads (89%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as rs1186870550; called by muse, mutect2, varscan2
- PRSS58 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 654/886 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs147205406; called by muse, mutect2, varscan2
- PSD | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 240/492 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs150370345; called by mutect2, varscan2
- PTPRK | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 301/583 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs867114186; called by muse, mutect2, varscan2
- PTPRR | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 119/254 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355830722, COSV51728664; called by muse, mutect2, varscan2
- PTPRT | c.4191G>A p.M1397I | Missense Mutation (SNP) | VAF 191/430 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61967372; called by muse, mutect2, varscan2
- PXDNL | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 128/624 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62480271; called by muse, mutect2, varscan2
- RAB30 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 155/321 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52626236, COSV52626779; called by muse, mutect2, varscan2
- RAD51AP2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 137/287 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV67587214; called by muse, mutect2, varscan2
- RASAL2 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 180/394 reads (46%) | SIFT tolerated (0.89); PolyPhen benign (0.145); catalogued as COSV62714389; called by muse, mutect2, varscan2
- RBMXL3 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 374/716 reads (52%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.636); catalogued as rs1392976094; called by muse, mutect2
- RGS3 | c.1184C>T p.S395L (on ENST00000350696 / NM_001282923.2; = p.S283L on NM_017790.4) | Missense Mutation (SNP) | VAF 222/483 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373897901; called by muse, mutect2, varscan2
- RGSL1 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 113/210 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1326048160; called by muse, mutect2, varscan2
- RIMBP3 | c.2948G>A p.R983K | Missense Mutation (SNP) | VAF 212/803 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as rs755966145; called by muse, mutect2, varscan2
- RLBP1 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 197/396 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51529309; called by muse, mutect2, varscan2
- RNF17 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 163/348 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99692110; called by muse, mutect2, varscan2
- RP1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 334/724 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1260107484; called by muse, mutect2, varscan2
- RPTOR | c.3821A>G p.N1274S | Missense Mutation (SNP) | VAF 182/361 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs759654534; called by muse, mutect2, varscan2
- RREB1 | c.3560C>T p.T1187I | Missense Mutation (SNP) | VAF 642/880 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs756679413; called by muse, mutect2, varscan2
- RTL3 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 323/654 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV100330084, COSV58184510; called by muse, mutect2, varscan2
- RTN1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 226/454 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV50726341; called by muse, mutect2, varscan2
- SALL1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 231/471 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV51756222; called by muse, mutect2, varscan2
- SALL3 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 351/666 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs745575293, COSV73306215; called by muse, mutect2, varscan2
- SAMD3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60774705; called by muse, mutect2, varscan2
- SCG2 | c.1449G>T p.W483C | Missense Mutation (SNP) | VAF 154/317 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs750571397, COSV59541860; called by muse, mutect2, varscan2
- SCN11A | c.2060T>A p.L687* | Nonsense Mutation (SNP) | VAF 130/130 reads (100%) | catalogued as rs1553637664; called by muse, mutect2, varscan2
- SCN11A | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 138/138 reads (100%) | catalogued as rs1553641553, COSV56571193; called by muse, mutect2, varscan2
- SCN2A | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 138/316 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV51836882; called by muse, mutect2, varscan2
- SCN3A | c.5852G>A p.G1951E | Missense Mutation (SNP) | VAF 183/393 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs1308612688; called by muse, mutect2, varscan2
- SCN9A | c.4596G>A p.M1532I (on ENST00000303354; = p.M1521I on NM_002977.3) | Missense Mutation (SNP) | VAF 152/365 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as COSV57610671; called by muse, mutect2, varscan2
- SEMG2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 223/448 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs929540146, COSV65647288; called by muse, mutect2, varscan2
- SEMG2 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 184/385 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as rs772776203; called by muse, mutect2, varscan2
- SI | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 149/304 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52275718; called by muse, mutect2, varscan2
- SLC12A3 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 166/366 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM117094; called by muse, mutect2, varscan2
- SLC22A24 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs765203877, COSV58223350; called by muse, mutect2, varscan2
- SLITRK2 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 274/598 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV59428313; called by muse, mutect2, varscan2
- SLITRK4 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 290/576 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs868983945, COSV62022882; called by muse, mutect2, varscan2
- SORL1 | c.2804G>A p.W935* | Nonsense Mutation (SNP) | VAF 217/217 reads (100%) | catalogued as COSV52764454, COSV99492493; called by muse, mutect2, varscan2
- SPACA1 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV99389369; called by muse, mutect2, varscan2
- SPATC1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 183/806 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs373999390; called by muse, mutect2, varscan2
- SPDYE4 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 134/272 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as rs374921150; called by muse, mutect2, varscan2
- SPHKAP | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 145/312 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as COSV60875987; called by muse, mutect2, varscan2
- SRRM5 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 284/565 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs149011418; called by muse, mutect2, varscan2
- STAP1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 163/196 reads (83%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as rs189780620, COSV99609211; called by muse, mutect2, varscan2
- STEAP4 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 206/822 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368689133, COSV57328052; called by muse, mutect2, varscan2
- STOX1 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 223/435 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs547404717, COSV53814237; called by muse, mutect2, varscan2
- SVEP1 | c.10177C>T p.H3393Y | Missense Mutation (SNP) | VAF 204/415 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99928565; called by muse, mutect2, varscan2
- SVEP1 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 171/372 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358712140; called by muse, mutect2, varscan2
- SYNE1 | c.11779T>C p.Y3927H | Missense Mutation (SNP) | VAF 187/374 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390497757; called by muse, mutect2, varscan2
- SYNPO2 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 57/480 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV61109264; called by muse, mutect2, varscan2
- TBC1D8B | c.530G>A p.W177* | Nonsense Mutation (SNP) | VAF 212/462 reads (46%) | catalogued as rs1556347033; called by muse, mutect2, varscan2
- TEX15 | c.2825G>A p.G942E (on ENST00000256246; = p.G1325E on NM_001350162.2) | Missense Mutation (SNP) | VAF 175/367 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs1323962609; called by muse, mutect2, varscan2
- TG | c.5021C>T p.P1674L | Missense Mutation (SNP) | VAF 132/637 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55065477; called by muse, mutect2, varscan2
- THSD7B | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs1347902701, COSV55656405; called by muse, mutect2, varscan2
- TMEM200A | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 194/399 reads (49%) | catalogued as rs267600806; called by muse, mutect2, varscan2
- TMEM247 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 42/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs74318890, COSV71363417; called by mutect2, varscan2
- TNXB | c.6475G>A p.E2159K (on ENST00000647633; = p.E1912K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 228/971 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.959); catalogued as rs764589468, COSV64472587; called by muse, mutect2, varscan2
- TOP3A | c.1706T>G p.V569G | Missense Mutation (SNP) | VAF 123/258 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1312031662; called by muse, mutect2, varscan2
- TRAPPC9 | c.3076C>T p.P1026S | Missense Mutation (SNP) | VAF 183/826 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.412); catalogued as rs1328343676; called by muse, mutect2, varscan2
- TRERF1 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 199/973 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.369); catalogued as rs747235795; called by muse, mutect2, varscan2
- TRIM32 | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 204/387 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1006879922; called by muse, mutect2, varscan2
- TRMT2B | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 196/417 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV58620783; called by muse, mutect2, varscan2
- TRRAP | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 447/595 reads (75%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs782664293; called by muse, mutect2, varscan2
- TSPAN2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 215/426 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV65690696; called by muse, mutect2, varscan2
- TTK | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 132/311 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773610148, COSV57881289, COSV57883755; called by muse, mutect2, varscan2
- TTN | c.28807G>A p.E9603K (on ENST00000591111; = p.E8676K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/316 reads (44%) | PolyPhen possibly damaging (0.814); catalogued as COSV60078694; called by muse, mutect2
- UNC5CL | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 171/713 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV99770893; called by muse, mutect2, varscan2
- URB1 | c.4144C>T p.L1382F | Missense Mutation (SNP) | VAF 264/510 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1184432349; called by muse, mutect2, varscan2
- USH2A | c.10667G>A p.G3556E | Missense Mutation (SNP) | VAF 163/379 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs397517968, COSV100232381, COSV56353201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP50 | c.794C>T p.S265F (on ENST00000616326; = p.S256F on NM_203494.5) | Missense Mutation (SNP) | VAF 152/320 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as COSV73214060; called by muse, mutect2, varscan2
- VAV2 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 166/317 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.112); catalogued as rs1458657832; called by muse, mutect2, varscan2
- VSTM2A | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 723/954 reads (76%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.986); catalogued as rs548506452, COSV56494837, COSV99043274; called by muse, mutect2, varscan2
- VWA3A | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 128/260 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs867523871; called by muse, mutect2, varscan2
- VWA3A | c.2769G>A p.M923I | Missense Mutation (SNP) | VAF 136/279 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1172418468; called by muse, mutect2, varscan2
- WWC1 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 339/661 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs146212755; called by muse, mutect2, varscan2
- ZIM3 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 160/361 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV54144746; called by muse, mutect2, varscan2
- ZNF335 | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100533520; called by muse, mutect2
- ZNF471 | c.1455A>C p.K485N | Missense Mutation (SNP) | VAF 165/365 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100340700; called by muse, mutect2, varscan2
- ZNF560 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 236/441 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as rs145492156, COSV100039152; called by muse, mutect2, varscan2
- ZNF572 | c.1379G>A p.R460K | Missense Mutation (SNP) | VAF 189/830 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV60002051, COSV60002574; called by muse, mutect2, varscan2
- ZNF652 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 246/490 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV62947678, COSV62948225; called by muse, mutect2, varscan2
- ZNF716 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 227/998 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as rs782641565, COSV70779637; called by muse, mutect2, varscan2
- ZP2 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1395231500, COSV54813907; called by muse, mutect2, varscan2
- ZP4 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 138/308 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as rs373960078; called by muse, mutect2, varscan2
- ZSCAN20 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 198/445 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100792716; called by muse, mutect2, varscan2
- ZSCAN20 | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 199/445 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs865914825; called by muse, mutect2, varscan2
- ABCA2 | c.2075G>A p.W692* (on ENST00000614293; = p.W662* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 145/307 reads (47%) | called by muse, mutect2, varscan2
- ABHD10 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 206/430 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC008397.2 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 198/424 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ACAN | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 265/553 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACHE | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 901/1181 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTC1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ACTN3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 132/276 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM32 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ADAMTS17 | c.2612del p.S871Tfs*16 | Frame Shift Del (DEL) | VAF 190/465 reads (41%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ADGRG6 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AKR1C4 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 187/371 reads (50%) | called by muse, mutect2, varscan2
- AL772284.1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 198/395 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANKRD13D | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 211/451 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ANKRD31 | c.106T>C p.L36= | Splice Region (SNP) | VAF 125/264 reads (47%) | called by muse, mutect2, varscan2
- ANO2 | c.502G>A p.E168K (on ENST00000356134 / NM_001278597.3; = p.E172K on NM_001278596.3) | Missense Mutation (SNP) | VAF 185/368 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ANOS1 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 277/512 reads (54%) | called by muse, mutect2, varscan2
- ANOS1 | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 278/512 reads (54%) | called by muse, mutect2, varscan2
- APAF1 | c.1774del p.M592Cfs*7 (on ENST00000551964 / NM_181861.2; = p.M581Cfs*7 on NM_001160.3) | Frame Shift Del (DEL) | VAF 143/326 reads (44%) | called by mutect2, pindel, varscan2
- ARHGEF35 | c.457T>C p.W153R | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0); called by mutect2, varscan2
- ASTN1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 135/291 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BMP6 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 214/819 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRAT1 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 665/886 reads (75%) | called by muse, mutect2, varscan2
- C17orf67 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 167/368 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C8orf76 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 175/747 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CACNA1I | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 471/696 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALCOCO2 | c.1126T>C p.Y376H | Missense Mutation (SNP) | VAF 152/314 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- CALHM1 | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 322/622 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CAMK1D | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 171/171 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMKV | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 241/243 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CARM1 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 157/327 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CATIP | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 206/468 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC120 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 246/547 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CCDC137 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 219/426 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CD163 | c.3019G>A p.D1007N | Missense Mutation (SNP) | VAF 187/442 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CDK19 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 127/285 reads (45%) | called by muse, mutect2, varscan2
- CEP128 | c.3164G>A p.R1055K | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.117); called by muse, mutect2
- CEP192 | c.6619C>T p.P2207S | Missense Mutation (SNP) | VAF 144/296 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP295 | c.4615A>G p.K1539E | Missense Mutation (SNP) | VAF 186/371 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEPT1 | c.394T>A p.L132M | Missense Mutation (SNP) | VAF 161/326 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP46 | c.6178G>A p.D2060N | Missense Mutation (SNP) | VAF 273/523 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CFAP54 | c.8669C>T p.S2890L | Missense Mutation (SNP) | VAF 105/194 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHAMP1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 238/793 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CHRNA5 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 133/289 reads (46%) | SIFT tolerated (0.38); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLIC5 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 228/939 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMYA5 | c.5530G>A p.E1844K | Missense Mutation (SNP) | VAF 200/422 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL12A1 | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 183/389 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL1A2 | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 552/732 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A1 | c.3476G>A p.G1159E | Missense Mutation (SNP) | VAF 269/479 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL6A5 | c.4364G>A p.G1455E | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX15 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CPN2 | c.64_76delinsCCTGTCC p.C22_C26delinsPVR | In Frame Del (DEL) | VAF 132/411 reads (32%) | called by pindel, varscan2*
- CPNE3 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 375/766 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CROCC | c.547T>C p.Y183H | Missense Mutation (SNP) | VAF 137/393 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CSH2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 197/1094 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CSMD1 | c.8827C>T p.L2943F (on ENST00000520002; = p.L2942F on NM_033225.6) | Missense Mutation (SNP) | VAF 190/411 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CUL4B | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CYRIA | c.392T>C p.F131S | Missense Mutation (SNP) | VAF 172/349 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DCAF8L1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 305/656 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- DCC | c.1140+7A>G | Splice Region (SNP) | VAF 83/157 reads (53%) | called by muse, mutect2, varscan2
- DDX55 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 149/299 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DEFB124 | c.198dup p.K67Qfs*3 | Frame Shift Ins (INS) | VAF 146/355 reads (41%) | called by mutect2, pindel, varscan2
- DISC1 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 262/533 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLG3 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 323/681 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DMRTC2 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 182/385 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DNAH8 | c.10168G>A p.G3390R | Missense Mutation (SNP) | VAF 143/619 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAJC13 | c.6525+1G>C p.X2175_splice | Splice Site (SNP) | VAF 114/236 reads (48%) | called by muse, mutect2, varscan2
- ELOA3C | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 193/1048 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELOVL5 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 209/886 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMID1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 362/589 reads (61%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMID1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 158/508 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPG5 | c.4378C>T p.Q1460* | Nonsense Mutation (SNP) | VAF 197/404 reads (49%) | called by muse, mutect2, varscan2
- EPYC | c.-13G>A | Splice Region (SNP) | VAF 63/138 reads (46%) | called by muse, mutect2, varscan2
- EYA4 | c.1246G>A p.E416K (on ENST00000531901 / NM_001301013.1; = p.E410K on NM_004100.5) | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM135A | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 166/335 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM170B | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 214/468 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- FAM83B | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 210/867 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM83B | c.2936T>C p.L979P | Missense Mutation (SNP) | VAF 182/822 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- FAR1 | c.125T>G p.V42G | Missense Mutation (SNP) | VAF 166/352 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- FASN | c.6575C>T p.S2192L | Missense Mutation (SNP) | VAF 216/465 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FBXO39 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 177/364 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FHDC1 | c.3422T>A p.L1141* | Nonsense Mutation (SNP) | VAF 230/264 reads (87%) | called by muse, mutect2, varscan2
- FMO3 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 201/398 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FNBP1 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 214/497 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FREM3 | c.3440G>A p.R1147K | Missense Mutation (SNP) | VAF 59/453 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- FREM3 | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 52/467 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- G3BP1 | c.983_986dup p.E329Dfs*2 | Frame Shift Ins (INS) | VAF 120/254 reads (47%) | called by mutect2, pindel, varscan2
- GDF2 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 215/489 reads (44%) | called by muse, mutect2, varscan2
- GLS | c.968T>C p.L323S | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLS2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 197/398 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA6L6 | c.2138G>C p.R713T | Missense Mutation (SNP) | VAF 82/478 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); called by muse, varscan2
- GRINA | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 319/674 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GSDMC | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 176/695 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HCN2 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC4 | c.760_763del p.S254Gfs*2 | Frame Shift Del (DEL) | VAF 142/147 reads (97%) | called by mutect2, pindel, varscan2
- HOXB5 | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 194/393 reads (49%) | called by muse, mutect2, varscan2
- HSD11B1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 177/363 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- HSD17B2 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 246/482 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- HTR4 | c.483G>A p.W161* | Nonsense Mutation (SNP) | VAF 134/264 reads (51%) | called by muse, mutect2, varscan2
- HYDIN | c.7294C>T p.L2432F | Missense Mutation (SNP) | VAF 118/248 reads (48%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 123/285 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- IGSF10 | c.3076T>C p.Y1026H | Missense Mutation (SNP) | VAF 168/381 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL31 | c.345A>G p.I115M | Missense Mutation (SNP) | VAF 160/354 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- ILDR1 | c.961G>A p.G321S (on ENST00000344209 / NM_001199799.2; = p.G277S on NM_175924.4) | Missense Mutation (SNP) | VAF 235/484 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ILDR2 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 138/306 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- IMPG1 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 170/333 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- INPPL1 | c.3323C>T p.T1108I | Missense Mutation (SNP) | VAF 301/662 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- IRS1 | c.2284C>T p.L762F | Missense Mutation (SNP) | VAF 272/552 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ITGB6 | c.2182T>G p.C728G | Missense Mutation (SNP) | VAF 175/433 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITIH6 | c.869T>A p.V290E | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- JAKMIP2 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 204/410 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KATNB1 | c.1653G>A p.W551* | Nonsense Mutation (SNP) | VAF 170/350 reads (49%) | called by muse, mutect2, varscan2
- KCTD16 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 212/457 reads (46%) | SIFT tolerated (0.89); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KIDINS220 | c.2645C>T p.S882L | Missense Mutation (SNP) | VAF 180/381 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- KMT2C | c.8066T>G p.L2689R | Missense Mutation (SNP) | VAF 218/925 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LINGO2 | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- LRP2 | c.12846C>G p.D4282E | Missense Mutation (SNP) | VAF 153/352 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LRRC39 | c.180T>G p.D60E | Missense Mutation (SNP) | VAF 122/316 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- LRRCC1 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 193/415 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRRN2 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 299/619 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGEE2 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 287/563 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAML3 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 293/335 reads (87%) | SIFT tolerated (0.44); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- MAP3K4 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 189/393 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF10 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 210/421 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MED12L | c.3445G>A p.G1149S | Missense Mutation (SNP) | VAF 156/318 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- MED23 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 107/230 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MEIS2 | c.643C>T p.P215S (on ENST00000561208 / NM_170675.5; = p.P202S on NM_002399.3) | Missense Mutation (SNP) | VAF 129/260 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MEP1B | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 157/311 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM2 | c.2851A>C p.I951L | Missense Mutation (SNP) | VAF 165/772 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MMP1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 195/428 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- MON2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 200/405 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- MS4A12 | c.276G>A p.G92= | Splice Region (SNP) | VAF 88/220 reads (40%) | called by muse, mutect2
- MTMR8 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 179/361 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC12 | c.9770C>T p.S3257L (on ENST00000379442; = p.S3114L on NM_001164462.1) | Missense Mutation (SNP) | VAF 344/4594 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- MUC16 | c.19891G>A p.D6631N | Missense Mutation (SNP) | VAF 198/407 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- MUC22 | c.2648C>A p.S883Y | Missense Mutation (SNP) | VAF 245/1543 reads (16%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC22 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 332/1426 reads (23%) | SIFT tolerated (0.6); called by muse, mutect2, varscan2
- MXRA5 | c.3779C>T p.S1260F | Missense Mutation (SNP) | VAF 280/569 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MYCBP2 | c.8648C>T p.P2883L (on ENST00000357337; = p.P2921L on NM_015057.5) | Missense Mutation (SNP) | VAF 169/352 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYH1 | c.2435+1G>A p.X812_splice | Splice Site (SNP) | VAF 121/292 reads (41%) | called by muse, mutect2, varscan2
- MYH4 | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO3B | c.3910G>A p.E1304K | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- MYOCD | c.2186A>T p.Q729L | Missense Mutation (SNP) | VAF 245/489 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MYRFL | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 132/323 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NACAD | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 203/1007 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAF1 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 194/229 reads (85%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCAN | c.3137-1G>A p.X1046_splice | Splice Site (SNP) | VAF 104/209 reads (50%) | called by muse, mutect2, varscan2
- NCAN | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 236/471 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- NEK10 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 181/181 reads (100%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEK11 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 200/392 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NELFE | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 218/960 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NLRP10 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 468/469 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- NLRP14 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 388/388 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP5 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 181/328 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- NOTCH1 | c.2243C>T p.T748I | Missense Mutation (SNP) | VAF 181/388 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- NOX1 | c.1083G>A p.W361* | Nonsense Mutation (SNP) | VAF 239/524 reads (46%) | called by muse, mutect2
- NRK | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 175/367 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUDCD1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 135/640 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OPN1MW | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 144/308 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR10J1 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 198/470 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- OR1A2 | c.62A>G p.Q21R | Missense Mutation (SNP) | VAF 162/317 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR51Q1 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 320/320 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- OR5V1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 187/791 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- OR7D2 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 212/429 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- P2RY2 | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 224/482 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PANX2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 318/512 reads (62%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAPPA2 | c.5033C>T p.S1678F | Missense Mutation (SNP) | VAF 106/205 reads (52%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAX6 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 341/341 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA13 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 239/523 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PCDHA8 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 142/319 reads (45%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHB8 | c.667A>G p.R223G | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PDCD6IP | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 144/144 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PDE1C | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 123/566 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PDGFRL | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 260/532 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGG | c.2072C>T p.S691F (on ENST00000453061 / NM_001127178.3; = p.S683F on NM_017733.4) | Missense Mutation (SNP) | VAF 262/392 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PLXDC1 | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 161/353 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- PMS2 | c.2111A>G p.D704G | Missense Mutation (SNP) | VAF 87/503 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNPLA5 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 318/506 reads (63%) | SIFT tolerated (0.55); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- POP1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 149/618 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PRAM1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 193/498 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PRKAA2 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 221/464 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCA | c.1137T>G p.D379E | Missense Mutation (SNP) | VAF 195/395 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- PRKCD | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 468/468 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PRR23B | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 224/453 reads (49%) | SIFT tolerated (0.89); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PTGER4 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 345/659 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PTPRN2 | c.2698A>G p.T900A | Missense Mutation (SNP) | VAF 199/881 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- R3HCC1 | c.1340C>T p.P447L (on ENST00000411463; = p.P407L on NM_001136108.3) | Missense Mutation (SNP) | VAF 203/421 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RADX | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 130/314 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RALGAPA1 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RASSF10 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 527/528 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.5045T>C p.V1682A | Missense Mutation (SNP) | VAF 196/456 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RBM20 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 215/458 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBM47 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 392/608 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); called by muse, varscan2
- RGL3 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 233/486 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RHBG | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 199/395 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIPK4 | c.1142C>T p.S381F (on ENST00000352483; = p.S333F on NM_020639.3) | Missense Mutation (SNP) | VAF 213/438 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNF170 | c.344G>T p.W115L | Missense Mutation (SNP) | VAF 185/363 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ROS1 | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 143/295 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RUNX3 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 225/469 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SALL3 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 389/806 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SCAPER | c.1264C>T p.L422F | Missense Mutation (SNP) | VAF 131/281 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCGN | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 165/694 reads (24%) | called by muse, mutect2, varscan2
- SCN10A | c.4562G>A p.G1521D | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- SEMG2 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 183/386 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SHC3 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 203/438 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SHISAL2B | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 130/294 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SIM1 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 205/425 reads (48%) | called by muse, mutect2, varscan2
- SIRPB2 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SKOR2 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 153/315 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SLC12A4 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A48 | c.371T>A p.V124E | Missense Mutation (SNP) | VAF 196/460 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLC29A4 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 154/722 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- SLC4A10 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 154/303 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLIT2 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 101/361 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMNDC1 | c.120+2T>C p.X40_splice | Splice Site (SNP) | VAF 110/227 reads (48%) | called by muse, mutect2, varscan2
- SP4 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 639/864 reads (74%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SPAST | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 139/271 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATC1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 614/1259 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SPIN4 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 284/522 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SPRY3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 378/792 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- STK26 | c.933G>A p.S311= | Splice Region (SNP) | VAF 138/281 reads (49%) | called by muse, mutect2, varscan2
- STK35 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2
- SULT1C3 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 200/432 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- SUSD2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 266/544 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYTL4 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 222/464 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAS2R41 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 199/863 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- TBX15 | c.1106C>T p.S369F (on ENST00000369429 / NM_001330677.2; = p.S263F on NM_152380.3) | Missense Mutation (SNP) | VAF 152/314 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TDRD15 | c.3428G>A p.G1143E | Missense Mutation (SNP) | VAF 118/245 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TENM1 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 198/392 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- TENT4B | c.1756C>T p.P586S (on ENST00000561678 / NM_001365323.2; = p.P571S on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/356 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TEX52 | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 87/211 reads (41%) | called by muse, mutect2, varscan2
- THOC2 | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 169/355 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- THOP1 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 179/349 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TLR8 | c.988G>A p.G330R (on ENST00000218032 / NM_138636.5; = p.G348R on NM_016610.4) | Missense Mutation (SNP) | VAF 204/421 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMC3 | c.2984C>T p.S995L | Missense Mutation (SNP) | VAF 201/436 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- TRPC6 | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 268/566 reads (47%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPM7 | c.686T>G p.L229W | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TTC6 | c.220A>T p.K74* (on ENST00000267368; = p.K1343* on NM_001310135.3) | Nonsense Mutation (SNP) | VAF 109/208 reads (52%) | called by muse, mutect2, varscan2
- TTN | c.13705G>A p.D4569N (on ENST00000591111; = p.D3642N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 185/430 reads (43%) | PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TTN | c.11234T>C p.V3745A (on ENST00000591111; = p.V3699A on NM_003319.4) | Missense Mutation (SNP) | VAF 269/514 reads (52%) | called by muse, mutect2
- TUBB | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 292/1213 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- UBR5 | c.5441C>T p.P1814L | Missense Mutation (SNP) | VAF 143/631 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- USH2A | c.10666G>A p.G3556R | Missense Mutation (SNP) | VAF 162/376 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- USP17L18 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 86/2148 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- USP24 | c.4987C>T p.H1663Y | Missense Mutation (SNP) | VAF 148/301 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VCP | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 206/397 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- VPS35 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 193/412 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- VTA1 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 116/211 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- WDR12 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 194/356 reads (54%) | called by muse, mutect2, varscan2
- WIZ | c.4451C>T p.A1484V (on ENST00000673675 / NM_001371589.1; = p.A389V on NM_021241.3) | Missense Mutation (SNP) | VAF 226/496 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- XRN2 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 136/137 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAN | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 531/717 reads (74%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZBTB18 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 212/464 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDBF2 | c.2888C>T p.P963L | Missense Mutation (SNP) | VAF 192/395 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZIM3 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 139/267 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1733T>A p.V578D | Missense Mutation (SNP) | VAF 328/445 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ZNF235 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 212/405 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF280C | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 146/282 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF507 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 181/395 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF606 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 148/327 reads (45%) | called by muse, mutect2, varscan2
- ZNF729 | c.1962dup p.P655Tfs*5 | Frame Shift Ins (INS) | VAF 167/471 reads (35%) | called by mutect2, pindel, varscan2
- ZNF735 | c.1121T>A p.I374N | Missense Mutation (SNP) | VAF 548/737 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ABCC2 | c.1836G>A p.R612= | Silent (SNP) | VAF 103/235 reads (44%) | called by muse, mutect2, varscan2
- ABCC3 | c.3072C>T p.F1024= | Silent (SNP) | VAF 139/273 reads (51%) | catalogued as rs1417320907; called by muse, mutect2, varscan2
- ABHD13 | c.342C>T p.S114= | Silent (SNP) | VAF 406/594 reads (68%) | catalogued as COSV101024037; called by muse, mutect2, varscan2
- ABHD4 | c.450C>T p.F150= | Silent (SNP) | VAF 184/365 reads (50%) | called by muse, mutect2, varscan2
- ACD | c.153C>T p.L51= | Silent (SNP) | VAF 281/555 reads (51%) | catalogued as rs1207134820, COSV54665585, COSV54667112, COSV54669526; called by muse, mutect2, varscan2
- ADAM28 | c.246C>T p.G82= | Silent (SNP) | VAF 96/225 reads (43%) | called by muse, mutect2, varscan2
- ADAM29 | c.1947C>T p.D649= | Silent (SNP) | VAF 59/519 reads (11%) | catalogued as rs751802258; called by muse, mutect2, varscan2
- ADAMTS16 | c.573C>T p.L191= | Silent (SNP) | VAF 203/388 reads (52%) | catalogued as rs373309305; called by muse, mutect2, varscan2
- ADCY8 | c.3126C>T p.A1042= | Silent (SNP) | VAF 138/687 reads (20%) | catalogued as rs765430601, COSV53898358, COSV53911273; called by muse, mutect2, varscan2
- AGXT2 | c.930G>A p.V310= | Silent (SNP) | VAF 193/391 reads (49%) | catalogued as rs751247124, COSV99183716; called by muse, mutect2, varscan2
- AKNA | c.1359C>T p.L453= | Silent (SNP) | VAF 167/369 reads (45%) | catalogued as rs140544301; called by muse, mutect2, varscan2
- ANK2 | c.3219C>T p.F1073= | Silent (SNP) | VAF 273/307 reads (89%) | catalogued as COSV52185380; called by muse, mutect2, varscan2
- ANK2 | c.4158C>T p.F1386= | Silent (SNP) | VAF 309/358 reads (86%) | catalogued as rs567608851, COSV52149537, COSV52173810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD30BL | c.210G>A p.A70= | Silent (SNP) | VAF 85/171 reads (50%) | catalogued as COSV99724410; called by muse, mutect2, varscan2
- ANO4 | c.1845C>T p.L615= (on ENST00000392977 / NM_001286615.2; = p.L580= on NM_178826.4) | Silent (SNP) | VAF 93/205 reads (45%) | catalogued as rs572173243, COSV54587903; called by muse, mutect2, varscan2
- AP3B2 | c.2211G>A p.Q737= | Silent (SNP) | VAF 150/310 reads (48%) | catalogued as rs544059884, COSV99916859; called by muse, mutect2, varscan2
- ARFGEF3 | c.417G>T p.A139= | Silent (SNP) | VAF 129/256 reads (50%) | called by muse, mutect2, varscan2
- ARID5B | c.1440C>T p.S480= | Silent (SNP) | VAF 160/350 reads (46%) | called by muse, mutect2, varscan2
- ASTN2 | c.3114G>A p.G1038= (on ENST00000313400 / NM_001365069.1; = p.G987= on NM_014010.5) | Silent (SNP) | VAF 199/413 reads (48%) | catalogued as rs781758780; called by muse, mutect2, varscan2
- ATAD5 | c.3870T>G p.A1290= | Silent (SNP) | VAF 168/381 reads (44%) | called by muse, mutect2, varscan2
- ATG2A | c.3033C>T p.F1011= | Silent (SNP) | VAF 294/641 reads (46%) | catalogued as rs376523340; called by muse, mutect2, varscan2
- ATG2A | c.1335T>G p.S445= | Silent (SNP) | VAF 223/453 reads (49%) | called by muse, mutect2, varscan2
- ATP2B3 | c.1257C>T p.I419= | Silent (SNP) | VAF 343/692 reads (50%) | called by muse, mutect2, varscan2
- ATRNL1 | c.1317T>C p.G439= | Silent (SNP) | VAF 125/305 reads (41%) | called by muse, mutect2, varscan2
- BDKRB1 | c.162G>A p.G54= | Silent (SNP) | VAF 245/485 reads (51%) | catalogued as rs1477568129, COSV53707233; called by muse, mutect2, varscan2
- BMP5 | c.147G>A p.R49= | Silent (SNP) | VAF 196/381 reads (51%) | called by muse, mutect2, varscan2
- BTBD16 | c.334C>T p.L112= | Silent (SNP) | VAF 197/431 reads (46%) | catalogued as rs745344769, COSV53263218; called by muse, mutect2, varscan2
- C10orf71 | c.3262C>T p.L1088= | Silent (SNP) | VAF 241/492 reads (49%) | called by muse, mutect2, varscan2
- C11orf80 | c.771C>T p.F257= | Silent (SNP) | VAF 220/445 reads (49%) | catalogued as rs758026448; called by muse, mutect2, varscan2
- CACNA1C | c.5514C>T p.P1838= | Silent (SNP) | VAF 256/559 reads (46%) | called by muse, mutect2, varscan2
- CACNA1S | c.4530C>T p.I1510= | Silent (SNP) | VAF 186/376 reads (49%) | called by muse, mutect2, varscan2
- CACNA1S | c.1338C>T p.T446= | Silent (SNP) | VAF 214/456 reads (47%) | catalogued as COSV62935863; called by muse, mutect2
- CAND2 | c.1263C>T p.T421= (on ENST00000456430 / NM_001162499.2; = p.T328= on NM_012298.3) | Silent (SNP) | VAF 196/196 reads (100%) | called by muse, mutect2, varscan2
- CCDC158 | c.2457G>A p.Q819= | Silent (SNP) | VAF 277/308 reads (90%) | catalogued as rs755792610; called by muse, mutect2, varscan2
- CCDC170 | c.768G>A p.L256= | Silent (SNP) | VAF 118/282 reads (42%) | called by muse, mutect2
- CCDC188 | c.12G>A p.L4= | Silent (SNP) | VAF 98/193 reads (51%) | called by muse, mutect2, varscan2
- CCDC9 | c.63C>T p.I21= | Silent (SNP) | VAF 141/321 reads (44%) | catalogued as rs779356635, COSV55721125; called by muse, mutect2, varscan2
- CCDC93 | c.1464C>T p.V488= | Silent (SNP) | VAF 196/403 reads (49%) | called by muse, mutect2, varscan2
- CCT8L2 | c.777C>T p.A259= | Silent (SNP) | VAF 215/471 reads (46%) | catalogued as COSV63462654; called by muse, mutect2, varscan2
- CD109 | c.4125A>G p.Q1375= | Silent (SNP) | VAF 138/290 reads (48%) | called by muse, mutect2, varscan2
- CD163 | c.1656C>T p.S552= | Silent (SNP) | VAF 221/450 reads (49%) | called by muse, mutect2, varscan2
- CD320 | c.126C>T p.T42= | Silent (SNP) | VAF 220/428 reads (51%) | catalogued as rs551205813; called by muse, mutect2, varscan2
- CDH16 | c.2055C>T p.I685= | Silent (SNP) | VAF 240/515 reads (47%) | catalogued as rs766156376, COSV55334532; called by muse, mutect2, varscan2
- CDH6 | c.1797C>T p.S599= | Silent (SNP) | VAF 275/553 reads (50%) | called by muse, mutect2, varscan2
- CEP135 | c.606T>C p.A202= | Silent (SNP) | VAF 130/324 reads (40%) | called by muse, mutect2, varscan2
- CFAP251 | c.3168T>C p.G1056= | Silent (SNP) | VAF 157/323 reads (49%) | called by muse, mutect2, varscan2
- CFAP47 | c.783C>T p.F261= | Silent (SNP) | VAF 210/439 reads (48%) | catalogued as COSV52893072; called by muse, mutect2, varscan2
- CFAP47 | c.1614G>A p.S538= | Silent (SNP) | VAF 100/239 reads (42%) | catalogued as COSV52888570; called by muse, mutect2, varscan2
- CLHC1 | c.526C>T p.L176= | Silent (SNP) | VAF 88/197 reads (45%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.96C>T p.P32= | Silent (SNP) | VAF 193/361 reads (53%) | called by muse, mutect2, varscan2
- COG6 | c.663G>A p.T221= | Silent (SNP) | VAF 119/249 reads (48%) | catalogued as rs746682554, COSV62998089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A1 | c.1119G>A p.L373= | Silent (SNP) | VAF 219/426 reads (51%) | catalogued as rs1434720892; called by muse, mutect2, varscan2
- CRY2 | c.1227C>T p.F409= | Silent (SNP) | VAF 171/374 reads (46%) | catalogued as COSV69889089; called by muse, mutect2, varscan2
- CYP2A7 | c.504C>T p.I168= | Silent (SNP) | VAF 162/341 reads (48%) | catalogued as rs775078619; called by muse, mutect2, varscan2
- CYP2C19 | c.1275C>T p.F425= | Silent (SNP) | VAF 147/294 reads (50%) | called by muse, mutect2, varscan2
- CYP2C9 | c.504C>T p.F168= | Silent (SNP) | VAF 120/280 reads (43%) | called by muse, mutect2, varscan2
- DDR1 | c.1185C>T p.F395= | Silent (SNP) | VAF 277/1071 reads (26%) | catalogued as rs1346154689, COSV61321131; called by muse, mutect2, varscan2
- DECR2 | c.621C>T p.A207= | Silent (SNP) | VAF 269/529 reads (51%) | catalogued as rs1454418233; called by muse, mutect2, varscan2
- DGKI | c.783G>A p.G261= | Silent (SNP) | VAF 142/598 reads (24%) | catalogued as rs777363541, COSV99936812; called by muse, mutect2, varscan2
- DNAH10 | c.7449G>A p.R2483= (on ENST00000409039; = p.R2422= on NM_207437.3) | Silent (SNP) | VAF 168/329 reads (51%) | called by muse, mutect2, varscan2
- DNAH5 | c.10737A>G p.Q3579= | Silent (SNP) | VAF 202/417 reads (48%) | called by muse, mutect2, varscan2
- DNAH5 | c.8364C>T p.F2788= | Silent (SNP) | VAF 209/405 reads (52%) | catalogued as COSV54241051; called by muse, mutect2, varscan2
- DNAH5 | c.5994G>A p.G1998= | Silent (SNP) | VAF 215/468 reads (46%) | catalogued as COSV54219587; called by muse, mutect2, varscan2
- DNAH7 | c.5988G>A p.K1996= | Silent (SNP) | VAF 104/216 reads (48%) | catalogued as COSV56776230; called by muse, mutect2, varscan2
- DNAJC16 | c.1431C>T p.I477= | Silent (SNP) | VAF 189/393 reads (48%) | called by muse, mutect2, varscan2
- DOCK11 | c.1839G>A p.K613= | Silent (SNP) | VAF 175/367 reads (48%) | catalogued as COSV52249203, COSV99353209; called by muse, mutect2, varscan2
- DOK7 | c.414C>T p.L138= | Silent (SNP) | VAF 555/854 reads (65%) | catalogued as rs771995943, CS127113; called by muse, mutect2, varscan2
- DPP6 | c.1431C>T p.I477= (on ENST00000377770 / NM_001364500.2; = p.I415= on NM_001936.5) | Silent (SNP) | VAF 471/633 reads (74%) | called by muse, mutect2, varscan2
- DPYS | c.303C>T p.F101= | Silent (SNP) | VAF 276/586 reads (47%) | catalogued as rs141057778; called by muse, mutect2, varscan2
- DSP | c.6744G>A p.E2248= | Silent (SNP) | VAF 111/495 reads (22%) | called by muse, mutect2, varscan2
- DTHD1 | c.1548G>A p.K516= (on ENST00000456874; = p.K351= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 444/695 reads (64%) | called by muse, mutect2, varscan2
- ELANE | c.495C>T p.I165= | Silent (SNP) | VAF 330/330 reads (100%) | catalogued as rs200923638, COSV55048181; called by muse, mutect2, varscan2
- ELFN1 | c.1749C>T p.F583= | Silent (SNP) | VAF 310/1347 reads (23%) | catalogued as rs1477754847; called by muse, mutect2, varscan2
- ELOA3D | c.819C>T p.P273= | Silent (SNP) | VAF 261/1725 reads (15%) | called by muse, mutect2, varscan2
- EMSY | c.3711C>T p.F1237= | Silent (SNP) | VAF 178/393 reads (45%) | called by muse, mutect2, varscan2
- ENAM | c.2772C>T p.S924= | Silent (SNP) | VAF 290/328 reads (88%) | catalogued as rs762153305; called by muse, mutect2, varscan2
- ENPP1 | c.174G>A p.E58= | Silent (SNP) | VAF 233/496 reads (47%) | catalogued as rs1337975655; called by muse, mutect2, varscan2
- EPG5 | c.5415G>A p.E1805= | Silent (SNP) | VAF 173/415 reads (42%) | called by muse, mutect2, varscan2
- EPHA1 | c.279C>T p.S93= | Silent (SNP) | VAF 253/1149 reads (22%) | called by muse, mutect2, varscan2
- EPHA10 | c.702G>A p.V234= | Silent (SNP) | VAF 274/560 reads (49%) | catalogued as rs1302356350; called by muse, mutect2, varscan2
- EXOC1 | c.138C>T p.R46= | Silent (SNP) | VAF 37/245 reads (15%) | called by muse, mutect2, varscan2
- EYA4 | c.996C>T p.F332= (on ENST00000531901 / NM_001301013.1; = p.F326= on NM_004100.5) | Silent (SNP) | VAF 128/265 reads (48%) | catalogued as rs773095472, CM138393, COSV62049831; called by muse, mutect2, varscan2
- FAM120C | c.2019G>A p.R673= | Silent (SNP) | VAF 236/484 reads (49%) | called by muse, mutect2, varscan2
- FAM47A | c.1554C>T p.R518= | Silent (SNP) | VAF 92/476 reads (19%) | catalogued as rs866449357, COSV60497385; called by muse, varscan2
- FAM83C | c.1233G>A p.R411= | Silent (SNP) | VAF 263/502 reads (52%) | called by muse, mutect2, varscan2
- FBXL7 | c.1299C>T p.L433= | Silent (SNP) | VAF 213/424 reads (50%) | catalogued as rs1448785651; called by muse, mutect2, varscan2
- FER1L6 | c.5511C>T p.F1837= | Silent (SNP) | VAF 705/982 reads (72%) | catalogued as rs1416395020; called by muse, mutect2, varscan2
- FHIT | c.15T>C p.F5= | Silent (SNP) | VAF 368/369 reads (100%) | called by muse, mutect2, varscan2
- FILIP1 | c.3303G>A p.K1101= | Silent (SNP) | VAF 132/283 reads (47%) | called by muse, mutect2, varscan2
- FIP1L1 | c.1389A>G p.R463= | Silent (SNP) | VAF 166/357 reads (46%) | called by muse, varscan2
- FLG | c.1092C>T p.S364= | Silent (SNP) | VAF 220/500 reads (44%) | called by muse, mutect2, varscan2
- FNDC1 | c.1989C>T p.F663= | Silent (SNP) | VAF 267/553 reads (48%) | catalogued as rs970040364, COSV51933126, COSV51939462; called by muse, mutect2, varscan2
- FNDC3B | c.2595C>T p.S865= | Silent (SNP) | VAF 268/553 reads (48%) | catalogued as rs748036776; called by muse, mutect2, varscan2
- FOLH1 | c.2013G>A p.L671= | Silent (SNP) | VAF 106/221 reads (48%) | called by muse, mutect2, varscan2
- FRMPD4 | c.255C>T p.P85= | Silent (SNP) | VAF 246/470 reads (52%) | catalogued as rs769101701; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABRD | c.909G>A p.R303= | Silent (SNP) | VAF 247/484 reads (51%) | catalogued as COSV66080686; called by muse, mutect2, varscan2
- GDPD4 | c.822C>T p.F274= | Silent (SNP) | VAF 159/328 reads (48%) | catalogued as rs1172008580, COSV60023462; called by muse, mutect2, varscan2
- GIPR | c.828C>T p.I276= | Silent (SNP) | VAF 197/411 reads (48%) | called by muse, mutect2, varscan2
- GLI2 | c.297C>T p.S99= | Silent (SNP) | VAF 257/571 reads (45%) | called by muse, mutect2, varscan2
- GRXCR2 | c.252G>A p.R84= | Silent (SNP) | VAF 196/447 reads (44%) | catalogued as rs746102300, COSV65060724; called by muse, mutect2, varscan2
- HDAC7 | c.531C>T p.L177= (on ENST00000427332; = p.L216= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 213/213 reads (100%) | catalogued as COSV50318474; called by muse, mutect2, varscan2
- HGD | c.1263G>A p.E421= | Silent (SNP) | VAF 173/376 reads (46%) | catalogued as COSV52197186; called by muse, mutect2, varscan2
- HHIPL2 | c.1125C>T p.S375= | Silent (SNP) | VAF 108/232 reads (47%) | catalogued as COSV58567797; called by muse, mutect2, varscan2
- HID1 | c.1164C>T p.F388= | Silent (SNP) | VAF 166/345 reads (48%) | catalogued as rs1262886212, COSV59351139; called by muse, mutect2, varscan2
- HIF1A | c.1959T>C p.S653= | Silent (SNP) | VAF 162/319 reads (51%) | called by muse, mutect2, varscan2
- HOOK2 | c.2070C>T p.F690= | Silent (SNP) | VAF 276/550 reads (50%) | catalogued as rs747678560, COSV99244744; called by muse, mutect2, varscan2
- HSF1 | c.663C>T p.S221= | Silent (SNP) | VAF 219/863 reads (25%) | catalogued as rs782550406; called by muse, mutect2, varscan2
- HYDIN | c.4416G>A p.Q1472= | Silent (SNP) | VAF 156/370 reads (42%) | called by muse, mutect2, varscan2
- IGHV3-21 | c.109C>T p.L37= | Silent (SNP) | VAF 200/621 reads (32%) | catalogued as rs782817560; called by muse, mutect2, varscan2
- IGKV6D-21 | c.270C>T p.F90= | Silent (SNP) | VAF 201/471 reads (43%) | called by muse, mutect2, varscan2
- IGSF9B | c.3141C>T p.F1047= | Silent (SNP) | VAF 314/315 reads (100%) | catalogued as rs757925560, COSV58064152, COSV58067565; called by muse, mutect2, varscan2
- IL17RA | c.1332C>T p.I444= | Silent (SNP) | VAF 234/462 reads (51%) | catalogued as rs1462547837, COSV60051216; called by muse, mutect2, varscan2
- IQANK1 | c.33A>C p.A11= | Silent (SNP) | VAF 216/975 reads (22%) | called by muse, mutect2, varscan2
- ISG15 | c.87G>A p.K29= | Silent (SNP) | VAF 253/542 reads (47%) | called by muse, mutect2, varscan2
- KCND2 | c.252C>T p.F84= | Silent (SNP) | VAF 601/824 reads (73%) | catalogued as rs1282232580, COSV58576379, COSV58585770; called by muse, mutect2, varscan2
- KCNH5 | c.2103C>T p.P701= | Silent (SNP) | VAF 194/418 reads (46%) | catalogued as rs112731796, COSV59770233; ClinVar: likely benign; called by muse, varscan2
- KCNH7 | c.351C>T p.N117= | Silent (SNP) | VAF 153/317 reads (48%) | called by muse, mutect2, varscan2
- KCNJ9 | c.1164G>A p.E388= | Silent (SNP) | VAF 140/298 reads (47%) | catalogued as rs1212136299; called by muse, mutect2, varscan2
- KDM4F | c.768C>T p.I256= | Silent (SNP) | VAF 222/448 reads (50%) | catalogued as rs899382042; called by muse, mutect2, varscan2
- KIF13A | c.5091C>T p.G1697= | Silent (SNP) | VAF 239/907 reads (26%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.141C>T p.I47= (on ENST00000396284; = p.I8= on NM_001080770.2) | Silent (SNP) | VAF 246/563 reads (44%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.228C>T p.F76= | Silent (SNP) | VAF 243/521 reads (47%) | called by muse, mutect2, varscan2
- KLF17 | c.975C>T p.F325= | Silent (SNP) | VAF 140/328 reads (43%) | catalogued as COSV64856345; called by muse, mutect2, varscan2
- KLHDC7A | c.2259C>T p.F753= | Silent (SNP) | VAF 201/427 reads (47%) | called by muse, mutect2, varscan2
- KLHL13 | c.1617C>T p.V539= | Silent (SNP) | VAF 196/391 reads (50%) | called by muse, mutect2, varscan2
- KRT26 | c.243G>A p.G81= | Silent (SNP) | VAF 154/314 reads (49%) | called by muse, mutect2, varscan2
- L1CAM | c.3501G>A p.P1167= | Silent (SNP) | VAF 268/560 reads (48%) | catalogued as rs1557089616, COSV62826715; called by muse, mutect2, varscan2
- LHFPL1 | c.6G>A p.R2= | Silent (SNP) | VAF 185/405 reads (46%) | catalogued as COSV64332893; called by muse, mutect2, varscan2
- LHX1 | c.753C>T p.F251= | Silent (SNP) | VAF 284/575 reads (49%) | called by muse, mutect2, varscan2
- LILRB1 | c.903C>T p.F301= (on ENST00000427581; = p.F265= on NM_006669.6) | Silent (SNP) | VAF 352/674 reads (52%) | catalogued as COSV61116452, COSV61116772, COSV61122370; called by muse, mutect2, varscan2
- LILRB4 | c.1191G>A p.Q397= (on ENST00000391733 / NM_001278428.3; = p.Q396= on NM_001278426.3) | Silent (SNP) | VAF 182/539 reads (34%) | called by muse, varscan2
- LINGO2 | c.1200C>T p.A400= | Silent (SNP) | VAF 134/288 reads (47%) | catalogued as rs1235734992; called by muse, mutect2, varscan2
- LNX1 | c.120C>T p.I40= | Silent (SNP) | VAF 51/481 reads (11%) | catalogued as rs764417661, COSV55784694; called by muse, mutect2, varscan2
- LOXHD1 | c.4221G>A p.E1407= | Silent (SNP) | VAF 163/330 reads (49%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3987C>T p.I1329= | Silent (SNP) | VAF 211/442 reads (48%) | called by muse, mutect2, varscan2
- LPA | c.2859C>T p.F953= | Silent (SNP) | VAF 180/371 reads (49%) | catalogued as rs1429400091; called by muse, mutect2, varscan2
- LPIN1 | c.30C>T p.S10= | Silent (SNP) | VAF 209/433 reads (48%) | called by muse, mutect2, varscan2
- LRRC19 | c.324C>T p.S108= | Silent (SNP) | VAF 123/125 reads (98%) | called by muse, mutect2, varscan2
- LRRIQ4 | c.393G>A p.K131= | Silent (SNP) | VAF 218/486 reads (45%) | called by muse, mutect2, varscan2
- LTN1 | c.177T>C p.S59= | Silent (SNP) | VAF 202/390 reads (52%) | called by muse, mutect2, varscan2
- MALRD1 | c.4446C>T p.F1482= | Silent (SNP) | VAF 111/238 reads (47%) | called by muse, mutect2, varscan2
- MCM3AP | c.3117A>G p.S1039= | Silent (SNP) | VAF 267/574 reads (47%) | called by muse, mutect2, varscan2
- MDN1 | c.6117G>T p.L2039= | Silent (SNP) | VAF 199/423 reads (47%) | called by muse, mutect2, varscan2
- MEX3B | c.867C>T p.S289= | Silent (SNP) | VAF 222/457 reads (49%) | catalogued as rs745615618; called by muse, mutect2, varscan2
- MGAM2 | c.3294C>T p.F1098= | Silent (SNP) | VAF 535/755 reads (71%) | called by muse, mutect2, varscan2
- MINDY4 | c.1098C>T p.D366= | Silent (SNP) | VAF 505/724 reads (70%) | called by muse, mutect2, varscan2
- MLH1 | c.813C>T p.S271= | Silent (SNP) | VAF 135/135 reads (100%) | catalogued as CD093760; called by muse, mutect2, varscan2
- MLIP | c.96G>A p.L32= | Silent (SNP) | VAF 175/723 reads (24%) | catalogued as COSV51427807; called by muse, mutect2, varscan2
- MMP9 | c.93C>T p.F31= | Silent (SNP) | VAF 260/520 reads (50%) | catalogued as rs200436945; called by muse, mutect2, varscan2
- MOSMO | c.267C>T p.S89= | Silent (SNP) | VAF 106/243 reads (44%) | called by muse, mutect2, varscan2
- MPST | c.156C>T p.R52= (on ENST00000341116 / NM_001369904.2; = p.R72= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 282/885 reads (32%) | called by muse, mutect2, varscan2
- MUC12 | c.5781C>T p.F1927= (on ENST00000379442; = p.F1784= on NM_001164462.1) | Silent (SNP) | VAF 274/338 reads (81%) | called by muse, mutect2, varscan2
- MUC12 | c.14280C>T p.F4760= (on ENST00000379442; = p.F4617= on NM_001164462.1) | Silent (SNP) | VAF 434/540 reads (80%) | catalogued as rs878876115; called by muse, mutect2, varscan2
- MUC16 | c.13965C>T p.F4655= | Silent (SNP) | VAF 223/463 reads (48%) | catalogued as rs1196346334, COSV67455345; called by muse, mutect2, varscan2
- MUC21 | c.6G>A p.K2= | Silent (SNP) | VAF 171/837 reads (20%) | catalogued as COSV66220363; called by muse, mutect2, varscan2
- MUC4 | c.9189C>T p.S3063= | Silent (SNP) | VAF 264/283 reads (93%) | called by muse, mutect2, varscan2
- MYH1 | c.1884G>A p.T628= | Silent (SNP) | VAF 129/266 reads (48%) | catalogued as rs769654863; called by muse, mutect2, varscan2
- MYH2 | c.1602C>T p.F534= | Silent (SNP) | VAF 141/326 reads (43%) | called by muse, mutect2, varscan2
- MYH4 | c.3684G>A p.L1228= | Silent (SNP) | VAF 122/269 reads (45%) | called by muse, mutect2, varscan2
- MYH4 | c.714C>T p.T238= | Silent (SNP) | VAF 78/199 reads (39%) | catalogued as rs757676293, COSV99701280; called by muse, mutect2, varscan2
- MYO18B | c.4068C>T p.F1356= | Silent (SNP) | VAF 134/285 reads (47%) | called by muse, mutect2, varscan2
- MYO18B | c.4998G>A p.Q1666= | Silent (SNP) | VAF 173/365 reads (47%) | catalogued as rs1370909942, COSV59133795; called by muse, mutect2, varscan2
- NBEA | c.705C>T p.F235= | Silent (SNP) | VAF 137/290 reads (47%) | catalogued as rs767011945; called by muse, mutect2, varscan2
- NCKAP1L | c.2616G>A p.V872= | Silent (SNP) | VAF 126/255 reads (49%) | catalogued as COSV99514892; called by muse, mutect2, varscan2
- NCR3 | c.360G>A p.G120= | Silent (SNP) | VAF 273/1138 reads (24%) | catalogued as rs1173897984; called by muse, mutect2, varscan2
- NLRP2 | c.1992G>A p.E664= | Silent (SNP) | VAF 195/435 reads (45%) | catalogued as COSV99672598; called by muse, mutect2, varscan2
- NPBWR1 | c.243C>T p.I81= | Silent (SNP) | VAF 525/1042 reads (50%) | called by muse, mutect2, varscan2
- NPY4R | c.513C>T p.S171= | Silent (SNP) | VAF 88/409 reads (22%) | called by muse, mutect2
- NTN4 | c.141C>T p.L47= | Silent (SNP) | VAF 229/476 reads (48%) | called by muse, mutect2, varscan2
- NUTM2D | c.2169G>A p.Q723= | Silent (SNP) | VAF 154/378 reads (41%) | called by muse, mutect2
- OBP2B | c.184T>C p.L62= | Silent (SNP) | VAF 187/406 reads (46%) | called by muse, mutect2, varscan2
- OR1D2 | c.276C>T p.I92= | Silent (SNP) | VAF 242/456 reads (53%) | called by muse, mutect2, varscan2
- OR1L1 | c.261C>T p.I87= (on ENST00000373686; = p.I37= on NM_001005236.3) | Silent (SNP) | VAF 213/473 reads (45%) | called by muse, mutect2, varscan2
- OR2T3 | c.537C>T p.I179= | Silent (SNP) | VAF 220/1155 reads (19%) | catalogued as rs965460968, COSV62083179; called by muse, mutect2
- OR2T34 | c.537C>T p.I179= | Silent (SNP) | VAF 424/881 reads (48%) | called by muse, mutect2, varscan2
- OR4N2 | c.255C>T p.F85= | Silent (SNP) | VAF 259/1043 reads (25%) | catalogued as rs139052676, COSV60052198; called by muse, mutect2, varscan2
- OR4N2 | c.318C>T p.F106= | Silent (SNP) | VAF 234/1016 reads (23%) | called by muse, varscan2
- OR4S1 | c.891G>A p.R297= | Silent (SNP) | VAF 182/356 reads (51%) | called by muse, mutect2, varscan2
- OR51V1 | c.462G>A p.R154= | Silent (SNP) | VAF 329/329 reads (100%) | catalogued as rs867904279, COSV58314319; called by muse, mutect2, varscan2
- OR5B2 | c.777G>A p.Q259= | Silent (SNP) | VAF 213/408 reads (52%) | called by muse, mutect2, varscan2
- OR5D14 | c.471C>T p.G157= | Silent (SNP) | VAF 228/462 reads (49%) | catalogued as rs142746293; called by muse, mutect2, varscan2
- OR5D16 | c.129G>A p.G43= | Silent (SNP) | VAF 274/577 reads (47%) | called by muse, mutect2
- OR5P3 | c.903G>A p.L301= | Silent (SNP) | VAF 281/283 reads (99%) | catalogued as rs1342345443; called by muse, mutect2, varscan2
- OR5T2 | c.750C>T p.I250= | Silent (SNP) | VAF 236/508 reads (46%) | called by muse, mutect2, varscan2
- OR6C75 | c.492G>A p.L164= | Silent (SNP) | VAF 150/314 reads (48%) | called by muse, varscan2
- OR8I2 | c.411C>T p.S137= | Silent (SNP) | VAF 163/338 reads (48%) | catalogued as COSV100135774, COSV100136036; called by muse, mutect2, varscan2
- OR8J2 | c.228C>T p.V76= | Silent (SNP) | VAF 170/326 reads (52%) | catalogued as rs747244609; called by muse, mutect2, varscan2
- P3H2 | c.435C>T p.F145= | Silent (SNP) | VAF 272/493 reads (55%) | called by muse, mutect2, varscan2
- PALLD | c.990C>T p.I330= | Silent (SNP) | VAF 62/457 reads (14%) | called by muse, mutect2, varscan2
- PASD1 | c.1956G>A p.Q652= | Silent (SNP) | VAF 279/557 reads (50%) | called by muse, mutect2, varscan2
- PCDHB15 | c.2004G>A p.Q668= | Silent (SNP) | VAF 317/719 reads (44%) | catalogued as rs781997741; called by muse, mutect2, varscan2
- PCSK5 | c.3672G>A p.R1224= | Silent (SNP) | VAF 204/411 reads (50%) | catalogued as COSV70448177; called by muse, mutect2, varscan2
- PDE1C | c.390C>T p.I130= | Silent (SNP) | VAF 541/760 reads (71%) | catalogued as rs776103841; called by muse, mutect2, varscan2
- PGLYRP4 | c.927C>T p.F309= | Silent (SNP) | VAF 174/334 reads (52%) | catalogued as COSV62834487; called by muse, mutect2, varscan2
- PHLDB2 | c.2436C>T p.S812= (on ENST00000393925 / NM_001134439.2; = p.S769= on NM_145753.2) | Silent (SNP) | VAF 123/278 reads (44%) | called by muse, mutect2, varscan2
- PIAS4 | c.81G>C p.V27= | Silent (SNP) | VAF 168/343 reads (49%) | called by muse, mutect2, varscan2
- PIM2 | c.867A>T p.P289= | Silent (SNP) | VAF 336/647 reads (52%) | called by muse, mutect2, varscan2
- PLCG2 | c.1917C>T p.N639= | Silent (SNP) | VAF 198/435 reads (46%) | called by muse, mutect2, varscan2
- PLCH1 | c.4932G>A p.G1644= (on ENST00000340059 / NM_001130960.2; = p.G1636= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 257/503 reads (51%) | called by muse, mutect2, varscan2
- PLD5 | c.825C>T p.F275= (on ENST00000442594; = p.F213= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 186/186 reads (100%) | catalogued as COSV100141681, COSV59146928; called by muse, mutect2, varscan2
- PLXNA2 | c.2661C>T p.F887= | Silent (SNP) | VAF 268/535 reads (50%) | called by muse, mutect2, varscan2
- POMK | c.804C>T p.F268= | Silent (SNP) | VAF 222/424 reads (52%) | called by muse, mutect2, varscan2
- POU5F1 | c.297A>G p.A99= | Silent (SNP) | VAF 375/1648 reads (23%) | catalogued as rs141749005; called by muse, mutect2, varscan2
- PPM1J | c.1431C>T p.G477= | Silent (SNP) | VAF 242/511 reads (47%) | catalogued as COSV53518871; called by muse, mutect2, varscan2
- PPP1R3A | c.1017G>A p.R339= | Silent (SNP) | VAF 134/568 reads (24%) | catalogued as rs1279895466, COSV52894341; called by muse, mutect2, varscan2
- PRAMEF10 | c.114G>A p.L38= | Silent (SNP) | VAF 111/324 reads (34%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.420G>A p.R140= | Silent (SNP) | VAF 222/488 reads (45%) | called by muse, mutect2, varscan2
- PRAMEF15 | c.528G>A p.R176= | Silent (SNP) | VAF 207/492 reads (42%) | called by muse, mutect2, varscan2
- PRKN | c.1021C>T p.L341= | Silent (SNP) | VAF 266/536 reads (50%) | called by muse, mutect2, varscan2
- PRRC2B | c.5811C>T p.P1937= | Silent (SNP) | VAF 193/412 reads (47%) | catalogued as rs1239103205; called by muse, mutect2, varscan2
- PRSS35 | c.690G>A p.G230= | Silent (SNP) | VAF 256/485 reads (53%) | called by muse, mutect2, varscan2
- PSD3 | c.580T>C p.L194= | Silent (SNP) | VAF 233/442 reads (53%) | called by muse, mutect2, varscan2
- PSG1 | c.1233C>T p.V411= | Silent (SNP) | VAF 246/548 reads (45%) | catalogued as rs528449196, COSV54945043; called by muse, mutect2, varscan2
- R3HDM2 | c.1998A>G p.V666= | Silent (SNP) | VAF 114/227 reads (50%) | called by muse, mutect2, varscan2
- RBM47 | c.345C>T p.F115= | Silent (SNP) | VAF 214/665 reads (32%) | catalogued as rs757455816, COSV55938178; called by muse, varscan2
155 further variants in this file (0 protein-altering or splice-affecting, 82 silent, 73 other) are not listed here.
